Somatic mutation profile of tumor specimen TCGA-BG-A0MT-01A (aliquot TCGA-BG-A0MT-01A-11D-A10B-09) from TCGA case TCGA-BG-A0MT, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 64.5 years (23,574 days).
Specimen TCGA-BG-A0MT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b4dc651-9d08-4a35-bc62-8160ff5460d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0MT-10A (Blood Derived Normal), aliquot TCGA-BG-A0MT-10A-01W-A10C-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee6293ef-21ee-43d0-ae97-9b399743be53

The open-access MAF lists 37 somatic variants for this specimen: 30 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 6, In Frame Del 4, Frame Shift Del 2, Splice Site 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGL | c.2929C>T p.R977* | Nonsense Mutation (SNP) | VAF 114/320 reads (36%) | catalogued as rs531425980, CM062412, COSV54052529; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1388_1393del p.G463_N465delinsD | In Frame Del (DEL) | VAF 228/456 reads (50%) | hotspot (GDC flag); catalogued as COSV55925085; called by mutect2, pindel, varscan2
- PTEN | c.635-1G>C p.X212_splice | Splice Site (SNP) | VAF 58/132 reads (44%) | hotspot (GDC flag); catalogued as rs876661024, CS090867, CS993675, COSV64289221, COSV64292432, COSV64296169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.5956G>A p.D1986N (on ENST00000272895 / NM_173076.3; = p.D1668N on NM_015657.3) | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.301); catalogued as rs746547558, COSV55949831; called by muse, mutect2, varscan2
- ADAM15 | c.2207+1G>A p.X736_splice | Splice Site (SNP) | VAF 82/137 reads (60%) | catalogued as COSV55126839; called by muse, varscan2
- C4BPA | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 101/508 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.596); catalogued as COSV65536354; called by muse, mutect2, varscan2
- CPOX | c.1068C>G p.S356R | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV51638276; called by muse, mutect2, varscan2
- DHRS4L2 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 153/378 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as COSV58729506; called by muse, mutect2, varscan2
- EIF2S3 | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 158/395 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53406063, COSV53406644; called by muse, mutect2, varscan2
- HECTD1 | c.5200G>C p.V1734L | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.031); catalogued as COSV67946257; called by muse, mutect2, varscan2
- KIF2A | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 98/259 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV66945479; called by muse, mutect2, varscan2
- KIF5B | c.2597G>A p.R866Q | Missense Mutation (SNP) | VAF 153/364 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV56652702; called by muse, mutect2, varscan2
- KIF7 | c.3031C>T p.R1011C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757590116, COSV51538975; called by muse, varscan2
- METAP1 | c.985A>G p.M329V | Missense Mutation (SNP) | VAF 214/548 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56443958; called by muse, mutect2, varscan2
- NUAK1 | c.407G>A p.S136N | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54603192; called by muse, mutect2, varscan2
- OR6B1 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 78/211 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV68770128; called by muse, mutect2, varscan2
- PRKN | c.875G>A p.G292D | Missense Mutation (SNP) | VAF 119/257 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV58224951; called by muse, mutect2, varscan2
- PTEN | c.30_32del p.S10del | In Frame Del (DEL) | VAF 84/276 reads (30%) | catalogued as rs1114167649; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- RGS16 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62375700; called by muse, mutect2, varscan2
- SCAMP3 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs751039504, COSV56944296; called by muse, mutect2
- SLC9A5 | c.1636G>A p.V546I | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs1335562611, COSV55362046; called by muse, mutect2, varscan2
- SPDYE5 | c.415T>C p.F139L | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); catalogued as COSV71596289, COSV71596316; called by muse, mutect2, varscan2
- USP48 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 117/304 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs763512444, COSV57609813; called by muse, mutect2, varscan2
- VHL | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 117/306 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869025650, CM058403, CM982008, COSV56544477, COSV56545017; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFAND3 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756741049, COSV54724609; called by muse, mutect2, varscan2
- ZMYM6 | c.1171G>C p.G391R | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.552); catalogued as COSV64120897; called by muse, mutect2, varscan2
- ARID1A | c.6411del p.T2138Hfs*62 | Frame Shift Del (DEL) | VAF 35/105 reads (33%) | called by mutect2, pindel, varscan2
- ATM | c.5835_5836del p.Q1946Vfs*18 | Frame Shift Del (DEL) | VAF 84/268 reads (31%) | called by mutect2, pindel, varscan2
- SEMA3F | c.199_204del p.D67_R68del | In Frame Del (DEL) | VAF 53/162 reads (33%) | called by mutect2, pindel, varscan2
- ZBTB7B | c.1074_1100del p.G359_T367del (on ENST00000292176; = p.G393_T401del on NM_001252406.3 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 18/39 reads (46%) | called by mutect2, varscan2
- ATF7 | c.18G>A p.P6= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as rs751643432, COSV60643717; called by muse, mutect2
- CDK15 | c.666C>T p.H222= (on ENST00000652192 / NM_001366386.2; = p.H171= on NM_139158.2) | Silent (SNP) | VAF 113/320 reads (35%) | catalogued as COSV53634217; called by muse, mutect2, varscan2
- FOXO4 | c.132G>A p.P44= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV58575257; called by muse, mutect2, varscan2
- OR14K1 | c.891C>T p.S297= | Silent (SNP) | VAF 62/296 reads (21%) | catalogued as rs753325788, COSV51721218; called by muse, mutect2, varscan2
- PUM2 | c.774C>T p.Y258= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV57580561; called by muse, mutect2, varscan2
- RTL5 | c.1092G>A p.K364= | Silent (SNP) | VAF 146/381 reads (38%) | catalogued as COSV65453385; called by muse, mutect2, varscan2
- OR2W5 | n.823C>T | RNA (SNP) | VAF 40/161 reads (25%) | catalogued as rs763106117; called by muse, mutect2, varscan2
